TARGET case TARGET-52-PAVYKD — Rhabdoid Tumor (TARGET-RT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/432499e1-1911-5a73-8bb9-4c8dedbb7fa9

Demographics
Sex at birth: female; Age at index: 0 years; Vital status: Dead; Days to death: 554 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Malignant rhabdoid tumor: ICD-O-3 morphology code: 8963/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 0.2 years (66 days); Year of diagnosis: 2013; Days to last follow up: 554 days (1.5 years); Pediatric kidney staging: Nephrectomy specimen with tumor that penetrates the renal capsule or involves the renal sinus with negative margins and negative lymph nodes, no distant metastasis.
   Treatment given: Protocol identifier: AREN03B2.

Follow-up (2 entries)
- Days to follow up: 248 days; Days to first event: 248 days; First event: Relapse.
- Days to follow up: 554 days (1.5 years); Year of follow up: 2015.

Biospecimens (2 samples)
- Sample TARGET-52-PAVYKD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-52-PAVYKD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 554
- Stage: II
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: RT
